TCGA case TCGA-BK-A6W4 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e7792b3-2b6c-47ac-acbe-3da7462a8321

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 62.3 years (22,766 days); Year of diagnosis: 2013; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IA; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 300 days.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 32.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes tested: 0.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 97 days; Days to treatment end: 119 days; Treatment dose: 3,750 cGy; Treatment outcome: Complete Response; Number of fractions: 5; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (2 entries)
- Days to follow up: 158 days; Disease response: Tumor Free.
- Days to follow up: 300 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 4+; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS / Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 107 kg; Height: 157 cm; BMI: 43.4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BK-A6W4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 180 mg.
  Slide TCGA-BK-A6W4-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-BK-A6W4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BK-A6W4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; History colorectal cancer: No; Diabetes diagnosis indicator: Yes; Hypertension diagnosis: Yes; Treatment outcome first course: Complete Remission/Response; History tamoxifen use: Never Used; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; History tamoxifen use: Never Used; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 300 days; disease-specific survival: no event (censored), 300 days; disease-free interval: no event (censored), 300 days; progression-free interval: no event (censored), 300 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BK-A6W4-01A-12D-A34P-01): tumor purity 1, ploidy 2, whole-genome doublings 0.
